Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMG-01A (Primary Tumor).

[page 1 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:
*Date - Date of Service:
Document Status:
Document Title:
Encounter info:
Contributor System:

* Final Report *

ORDERING PHYSICIAN:
Ordering Physician:

PRE-OPERATIVE DIAGNOSIS:
Prostate cancer

MICROSCOPIC DESCRIPTION:
A-E: See final microscopic-diagnosis.

F: Sections of the bladder and prostate show a poorly differentiated, invasive urothelial carcinoma. The tumor cells grow in trabeculae and display a high nuclear to cytoplasmic ratio and a high mitotic rate. Nuclear pleomorphism is moderate and nuclear irregularities are present. The chromatin is coarsely clumped with areas of irregular clearing with moderate to sparse eosinophilic cytoplasm. Cell borders are indistinct. Tumor cells deep invade the prostatic parenchyma approaching to within 0.1 cm of the inked prostatic capsular radial margin (F17).

G-V: See final microscopic-diagnosis.

Signature Line
Signed by:
ELECTRONIC SIGNATURE

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right urethral margin" (sic). It consists of a 0.3 cm length of ureter 0.5 cm in diameter. Entirely submitted in one cassette for frozen section.

B: The specimen is received fresh from the O.R. and labeled "Left urethral margin" (sic). It consists of a 0.3 cm length of ureter 0.2 cm in diameter. Entirely submitted in one cassette for frozen section.

C: The specimen is received fresh from the O.R. and labeled "Peritoneal mass." It consists of a 3 x 3 x 0.7 cm, greasy, yellow to off white tissue fragment. Cut section reveals a lobular, green-yellow architecture with fine, white

Printed by:
Printed on:

Page 1 of 8
(Continued)

ICD O-3
Carcinoma, urothelial NOS
Site: Bladder NOS
8120/3
067.9
J126/14

[page 2 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

streaks. Submitted in two cassettes, one cassette for frozen and two cassettes for permanent.

D: The specimen is received fresh from the O.R. and labeled "Inferior urethral margin." It consists of a 0.4 x 0.4 x 0.2 cm, tan tissue fragment. Entirely submitted for frozen section.

E: The specimen is received fresh from the O.R. and labeled "Posterior urethral margin." It consists of a 1 x 0.5 x 0.4 cm, tan tissue fragment. Entirely submitted for frozen section.

F: The specimen is received fresh from the O.R. and labeled "Bladder & prostate." It consists of a 20 x 13.5 x 5.5 cm cystoprostatectomy specimen. The peritoneum measures 17 x 12 cm and is grossly uninvolved. The bladder measures 5 x 5 x 3 cm. The prostate measures approximately 2.3 x 3 x 3 cm to palpation but is firmly attached to a 5 x 4 x 3 cm, palpable mass at the neck of the bladder. The specimen is opened along its anterior surface to reveal the following: A 5 x 4 x 3 cm, lobulated, exophytic mass that is located in the portion of the bladder inferior margin. A portion of the mass detached from the specimen upon opening. The surface of the mass displays stellate ulceration and necrosis. The mass is located at the interface between the bladder and the prostate. Serial section reveals a flat demarcation between the mass and the prostate. The cut surface of the mass is firm and white-tan and displays an interface with the prostatic parenchyma. The prostatic parenchyma is not lobulated; however, fine, protruding, yellow-white, punctate areas are present in the right lobe of the prostate. The prostatic urethra measures 1.5 cm in length and is grossly involved. The verumontanum is excavated. The uninvolved bladder mucosa is purple and edematous. No other lesions are noted. The uninvolved wall is 0.6 cm in thickness. The maximum depth of invasion is 1.1 cm. The bladder wall thickness in the area of invasion cannot be measured as it occurs in the bladder neck. Representative sections are submitted in 25 cassettes (see summary).

G: The specimen is received fresh from the O.R. and labeled "Posterior urethral margin." It consists of a 1.4 x 0.5 x 0.3 cm, tan tissue fragment. Entirely submitted for frozen section.

H: The specimen is received fresh from the O.R. and labeled "Anterior urethral margin." It consists of a 1.4 x 1 x 0.6 cm, tan tissue fragment. Entirely submitted for frozen section.

I: The specimen is received fresh from the O.R. and labeled "Lateral urethral margin." It consists of a 0.5 x 0.4 x 0.3 cm tissue fragment and a 0.7 x 0.4 x 0.3 cm tissue fragment. Entirely submitted for frozen section.

J: The specimen is received in formalin and labelled "Right common iliac lymph nodes." It consists of a 2.2 x 2 x 0.7 cm aggregate of greasy, yellow tissue fragments. Entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Right obturator lymph nodes." It consists of 7 x 3.5 x 1.4 cm of greasy, yellow tissue. Entirely submitted in five cassettes.

L: The specimen is received in formalin and labeled "Right internal iliac lymph nodes." It consists of 5 x 4 x 1 cm of greasy, yellow tissue fragments. Entirely submitted in three cassettes.

Printed by:
Printed on:

Page 2 of 8
(Continued)

[page 3 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

M: The specimen is received in formalin and labeled "Presacral lymph nodes." It consists of a 4 x 3 x 1.5 cm of greasy, yellow tissue. Entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Left obturator lymph nodes." It consists of a 5 x 2 x 0.8 cm of greasy, yellow tissue fragment. Entirely submitted in three cassettes.

O: The specimen is received in formalin and labeled "Left external iliac lymph nodes." It consists of 5 x 5 x 1 cm of greasy, yellow tissue. Submitted in in three cassettes.

P: The specimen is received in formalin and labeled "Right hypogastric lymph nodes." It consists of a 1.5 x 0.8 x 0.5 cm, purple-tan tissue fragment. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Obturator vessel". It consists of a 1.5 x 1.2 x 0.5 cm of portion of vascular tissue. Entirely submitted in a single cassette.

R: The specimen is received in formalin and labeled "Left common iliac lymph nodes." It consists of a 1.5 x 1.5 x 0.5 cm, greasy, yellow tissue fragment. Entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Left presciatic lymph nodes." It consists of a 2 x 0.7 x 0.3 cm, greasy, yellow tissue fragment. Entirely submitted in one cassette.

T: The specimen is received in formalin and labeled "Appendix." It consists of a vermiform appendix measuring 4.8 cm in length and 0.5 cm in diameter. The serosal surface is unremarkable with the exception of creeping fat reaction located from the tip to 1 cm proximal to the tip. Representative sections in one cassette.

U: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a 0.7 cm length of ureter, 0.5 cm in diameter. Entirely submitted in one cassette.

V: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a 1.5 cm disrupted length of ureter, 0.4 cm in diameter. Entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right ureteral margin all embedded
BFS: frozen section, left ureteral margin all embedded
CFS: frozen section, peritoneal mass
C1,2: peritoneal mass
DFS: frozen section, inferior urethral margin all embedded
EFS: frozen section, posterior urethral margin all embedded
F1: uninvolved bladder mucosa
F2: left ureterovesical junction

Printed by:
Printed on:

Page 3 of 8
(Continued)

[page 4 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

F3: right ureterovesical junction
F4: left ureter
F5: right ureter
F6: additional section of uninvolved bladder mucosa
F7,8: right distal prostate with tumor
F9: left distal prostate
F10,11: right mid anterior prostate with tumor
F12: right mid posterior prostate
F13-16: left mid anterior prostate with tumor
F17: left mid posterior prostate
F18-20: right proximal prostate arranged anterior to posterior
F21-23: left proximal prostate arranged anterior to posterior
F24: right seminal vesicle
F25: left proximal posterior prostate
GFS: frozen section, posterior urethral margin all embedded
HFS: frozen section, anterior urethral margin all embedded
IFS: frozen section, lateral urethral margin all embedded
J: right common iliac lymph nodes all embedded
K1,2: single, palpable, right common iliac lymph node, multiple sections
K3-5: remaining tissue
L1-3: right internal iliac lymph nodes all embedded
M: presacral lymph nodes all embedded
N1,2: single left obturator lymph node
N3: remaining tissue
O: left external iliac lymph nodes
P: right hypogastric lymph nodes all embedded
Q: obturator vessel all embedded
R: left common iliac lymph nodes all embedded
S: left presciatic lymph nodes all embedded
T: appendix
U: left proximal ureter all embedded
V: right proximal ureter all embedded

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right ureteral margin:
- no carcinoma in situ identified

Printed by:
Printed on:

Page 4 of 8
(Continued)

[page 5 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

BFS: Left ureteral margin:

- no carcinoma in situ identified

CFS: Peritoneal mass:

- fat necrosis

DFS: Inferior urethral margin:

- focus of carcinoma in situ in gland duct

EFS: Posterior urethral margin:

- carcinoma in situ in periurethral glands

GFS: Posterior urethral margin:

- no carcinoma in situ

HFS: Anterior urethral margin:

- carcinoma in situ in periurethral glands

IFS: Lateral urethral margin:

- no carcinoma in situ

DIAGNOSIS COMMENT:

On specimen D, the frozen section shows a focus of carcinoma in situ in a gland. This is not present on the permanent section.

There is a low grade papillary urothelial carcinoma in the region of the bladder neck and mid region of the bladder. A morphologically distinct high grade tumor arises in the bladder neck and prostatic urethra. This is a high grade tumor that invades the prostate and bladder neck. The low grade tumor is noninvasive.

FINAL DIAGNOSIS:

RADICAL CYSTOPROSTATECTOMY, BILATERAL PELVIC LYMPH NODE DISSECTION, APPENDECTOMY:

RIGHT URETERAL MARGIN (A):

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT URETERAL MARGIN (B):

Printed by:

Printed on:

Page 5 of 8

(Continued)

[page 6 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

PERITONEAL MASS (C):

FROZEN SECTION DIAGNOSIS:

- FAT NECROSIS

FINAL DIAGNOSIS:

INFARCTED APPENDICES EPILOICAE

INFERIOR URETHRAL MARGIN (D):

FROZEN SECTION DIAGNOSIS:

- FOCUS OF CARCINOMA IN SITU IN GLAND DUCT

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU IN A GLAND DUCT (SEE COMMENT)

POSTERIOR URETHRAL MARGIN (E):

FROZEN SECTION DIAGNOSIS:

- CARCINOMA IN SITU IN PERIURETHRAL GLANDS

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IDENTIFIED

BLADDER AND PROSTATE (F):

BLADDER:

- INVASIVE UROTHELIAL CARCINOMA, GRADE 4/4, WITH EXTENSION INTO PROSTATIC DUCTS, GLANDS, AND STROMA
- URETERS AND PROSTATIC RADIAL MARGIN, FREE OF TUMOR
- PAPILLARY UROTHELIAL CARCINOMA, GRADE 2/4 (SEE COMMENT)
- EJACULATORY DUCT AND SEMINAL VESICLE INVOLVEMENT IDENTIFIED
- NO EXTENSION INTO PERIPROSTATIC SOFT TISSUE IDENTIFIED
- TUMOR PRESENT WITHIN LYMPHOVASCULAR SPACES
- THE NON-NEOPLASTIC PROSTATE SHOWS BENIGN GLANDULAR AND STROMAL HYPERPLASIA
- NO HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA OR PROSTATIC ADENOCARCINOMA IDENTIFIED
- NO TUMOR SEEN IN TWO PERIVESICAL LYMPH NODES

POSTERIOR URETHRAL MARGIN (G):

FROZEN SECTION DIAGNOSIS:

Printed by:

Printed on:

Page 6 of 8
(Continued)

[page 7 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

- NO CARCINOMA IN SITU IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

ANTERIOR URETHRAL MARGIN (H):

FROZEN SECTION DIAGNOSIS:

- CARCINOMA IN SITU IN PERIURETHRAL GLANDS

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU IN PERIURETHRAL GLANDS

LATERAL URETHRAL MARGIN (I):

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT COMMON ILIAC LYMPH NODES (J):

- NO EVIDENCE OF MALIGNANCY IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT OBTURATOR LYMPH NODES (K):

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT INTERNAL ILIAC LYMPH NODES (L)

- NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES EXAMINED (0/9)

PRESACRAL LYMPH NODES (M):

- NO EVIDENCE OF MALIGNANCY IN 12 LYMPH NODES EXAMINED (0/12)

LEFT OBTURATOR LYMPH NODES (N):

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT EXTERNAL ILIAC LYMPH NODES (O):

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT HYPOGASTRIC LYMPH NODES (P):

- NO EVIDENCE OF MALIGNANCY IN TEN LYMPH NODES EXAMINED (0/10)

OBTURATOR VESSEL (Q):

- NO SIGNIFICANT PATHOLOGIC CHANGE

- NO EVIDENCE OF MALIGNANCY

Printed by:

Printed on:

Page 7 of 8

(Continued)

[page 8 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

LEFT COMMON ILIAC LYMPH NODE (R):

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LEFT PRESACRAL LYMPH NODES (S):

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES EXAMINED (0/2)

APPENDIX (T):

- DISTAL LUMINAL OBLITERATION
- NO FURTHER SIGNIFICANT PATHOLOGIC CHANGE

LEFT PROXIMAL URETER (U):

- BENIGN URETER WALL, NO MUCOSA
- NO EVIDENCE OF MALIGNANCY

RIGHT PROXIMAL URETER (V):

- BENIGN URETER
- NO EVIDENCE OF MALIGNANCY

PATHOLOGIC TNM STAGE: pT4aNOMX [NO TUMOR SEEN IN 51 LYMPH NODES (0/51)]

Completed Action List:

Printed by:
Printed on:

Page 8 of 8
(End of Report)

Source: NCI Genomic Data Commons file 74516cc7-66d0-429c-9c50-29a009972d91 (TCGA-XF-AAMG.3B9E30D8-1671-465F-9425-951912C1ECF5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).